Surgical pathology report (de-identified scan), TCGA case TCGA-K1-A42W, project TCGA-SARC (Sarcoma), tissue source site University of Pittsburgh, specimen TCGA-K1-A42W-01A (Primary Tumor).

[page 1 of 3]
FINAL DIAGNOSIS:

PART 1: DISTAL PANCREAS, RESECTION -

- A. ~~LEIOMYOSARCOMA~~, INTERMEDIATE GRADE (3.5 CM), INVOLVING PANCREATIC PARENCHYMA (see comment).
- B. PANCREATIC MARGIN IS FREE OF TUMOR.
- C. PANCREATIC PARENCHYMA WITH FOCAL CHRONIC PANCREATITIS AND LOW GRADE PanIN.
- D. FOUR BENIGN LYMPH NODES (0/4).
- E. PATHOLOGIC STAGE: pT1b N0 Mx.

ICD-O-3

Leiomyosarcoma, NOS
8890/3

Site: Retroperitoneum
QW 12/24/12 C48.0

PART 2: SPLEEN, SPLENECTOMY -

- A. SPLEEN WITH NO SIGNIFICANT ABNORMALITY.
- B. THREE BENIGN LYMPH NODES (0/3).

PART 3: LYMPH NODE, HEPATIC ARTERY, EXCISION - TWO BENIGN LYMPH NODES (0/2).

COMMENT:

The neoplasm is composed of pleomorphic spindled cells arranged in fascicles with focal necrosis (approximately 5%) and mitoses of 21 per 50 high power fields. The tumor is strongly immunoreactive for actin and desmin and Ki67 decorates approximately 20% of the tumor nuclei. CD34 highlights the vasculature. S100, AE1/3, DOG1, CK17 and HMB45 are negative. These results together with the morphology support an intermediate grade leiomyosarcoma. The tumor may represent a primary intra-abdominal/ retroperitoneal leiomyosarcoma and has been staged as such in this report. Alternatively, the tumor may represent a metastasis. A uterine primary may be considered. Clinical and radiographic correlation is suggested.

has also reviewed part 2 in this case.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY SOFT TISSUE TUMORS

SPECIMEN TYPE: Radical resection
TUMOR SITE: pancreas
TUMOR DEPTH: Deep: Intra-abdominal
Deep: Retroperitoneal
TUMOR SIZE: Greatest dimension: 3.5 cm
Additional dimensions: 3.1 cm
PRERESECTION TREATMENT: No therapy
HISTOLOGIC TYPE (WHO classification of soft tissue tumors): leiomyosarcoma
RESULTS OF ANCILLARY STUDIES: see comment
MITOTIC RATE: 6/10 high-power fields
MACROSCOPIC NECROSIS: Absent
MICROSCOPIC NECROSIS: Present: Extent: 5%
GRADE: System used: r.
Grade: Grade 2
PATHOLOGIC STAGING (pTNM): pT1b
pN0

Primary tumor per documentation by RSS,
for

Number regional lymph nodes examined: 9
Number regional lymph nodes involved: 0

MARGINS: pMX
Margins uninvolved by sarcoma

MICROSCOPIC VENOUS/LYMPHATIC (LARGE/SMALL VESSEL) INVASION:

PERINEURAL INVASION: Absent

Diagnostic Discrepancy		
Just/Syn. chronic Primary History		

for
8/14/12

[page 2 of 3]
Reason for the Exam: PANCREATIC MASS

EXAMINATION PERFORMED:

CT ABDOMEN WITH AND WITHOUT CONTRAST

CLINICAL INDICATION:

Pancreatic mass with pathology consistent with spindle cell carcinoma.

TECHNIQUE:

Helical 2.5mm images were obtained from the lung apices through the pelvis following the uneventful IV administration of 125cc of Isovue 370. Post-contrast images were obtained during arterial and venous phases per pancreatic mass protocol.

COMPARISON:

None.

FINDINGS:

Lung: There is mild emphysema; otherwise lungs are clear. There is no effusion or pneumothorax. Heart size is normal with no effusion. No enlarged thoracic lymph nodes are noted.

Abdomen: There is a 3x3cm hypo-attenuating and hypovascular lesion in proximal body of pancreas. The lesion is round and is well demarcated with has lower attenuation than the rest of pancreas on all phases. There is no finding of invasion to adjacent organs or vascular structures. The remainder of the pancreas is normal with no additional focal lesion, atrophy or ductal dilatation.

There is a small hypoattenuating lesion in segment 8 of liver, measuring 1.3cm. The lesion is hypoattenuating on the unenhanced and arterial phases; on the portal phase, there is the suggestion of subtle discontinuous nodular peripheral enhancement, favoring a benign etiology (such as sclerosed hemangioma). The liver is otherwise normal. The hepatic vessels are patent. The spleen and adrenal glands are unremarkable. There is a 7mm hypoattenuating lesion in the midpole of the left kidney which is too small to characterize. The kidneys are otherwise normal. There is no intra-abdominal fluid collection or enlarged lymph nodes. The stomach and loops of small and large bowel are normal in course and appearance.

Pelvis: The rectum, sigmoid, appendix, uterus and adnexa and bladder are unremarkable. There is no intrapelvic fluid collection or enlarged lymph nodes. No osseous abnormalities are identified.

IMPRESSION:

CHEST:

1. MILD EMPHYSEMA; NO FINDINGS OF METASTASIS.

ABDOMEN:

1. 3X3CM WELL-DEFINED HYPOVASCULAR MASS WITHIN THE PROXIMAL BODY OF PANCREAS CORRELATING TO PATIENT'S KNOWN SARCOMA; THERE IS NO FINDING OF INVASION INTO VASCULAR STRUCTURES OR ADJACENT ORGANS.
2. SMALL HYPOATTENUATING LESION IN SEGMENT 8 OF THE LIVER IS FAVORED TO BE DUE TO A BENIGN ETIOLOGY WITH DIFFERENTIAL CONSIDERATIONS INCLUDING SCLEROSSED HEMANGIOMA VERSUS CYST. FOLLOW-UP CT CAN ASSESS STABILITY.

PELVIS:

1. UNREMARKABLE PELVIC CT.

[page 3 of 3]
CLINICAL HISTORY:

-year-old female status post laparoscopic distal pancreatectomy and splenectomy for pancreatic leiomyosarcoma on

COMPARISON:

TECHNIQUE:

2.5mm axial images of the chest, abdomen, and pelvis were obtained with 125 cc of Isovue-370 intravenous contrast and Read-Cat oral contrast in the portal venous phase. Coronal and sagittal reformats were also provided.

FINDINGS:

CHEST:

The visualized thyroid gland and great vessels are unremarkable. A 3 mm subpleural right lower lobe nodule is stable since representing a benign lesion. The lungs are clear without suspicious pulmonary nodules, consolidation, or pleural effusion. There are no enlarged thoracic lymph nodes. The heart size is normal with no pericardial effusion.

ABDOMEN:

The suspicious hypodense lesion in segment 7 has enlarged, measuring 1.3cm from 1.1cm previously. Several new hypodense lesions including segment 4A 1.3cm focus and 2.4x2.7cm segment 6 lesion are new and concerning for metastases. The nonenhancing segment 4A lesion likely representing a hepatic cyst is unchanged. The spleen, distal pancreas, and gallbladder are surgically absent. There is no evidence of disease recurrence in the surgical bed. The adrenal glands and right kidney are unremarkable. A lower pole posterior left renal cyst is unchanged. The small and large bowel are normal in caliber without focal wall thickening. There is no free fluid, free air, or enlarged lymph nodes in the abdomen or pelvis.

Mild atherosclerotic calcifications are seen in a normal caliber abdominal aorta. A 5 cm fat containing umbilical hernia is unchanged.

PELVIS:

The urinary bladder, uterus, ovaries, and rectum are unremarkable. Sigmoid diverticulosis is seen with no CT evidence of diverticulitis. No osteoblastic or lytic lesions are identified in the chest, abdomen, or pelvis.

IMPRESSION:

CHEST:

1. No metastatic disease in the chest.

ABDOMEN:

1. Development of multiple hypodense lesions compatible with metastatic disease in segments 4A, 6, and 7 with the largest measuring 2.4x2.7cm in segment 6.
2. No evidence of local disease recurrence or enlarged lymph nodes.
3. Unchanged fat containing umbilical hernia.

PELVIS:

1. No acute abnormalities in the pelvis.
2. Sigmoid diverticulosis.

CLINICAL HISTORY:

Liver lesion. History of leiomyosarcoma of pancreas. Date of Event

SOURCE OF SPECIMEN:

LIVER, US-GUIDED FINE NEEDLE ASPIRATION

Addendum

The liver FNA was reviewed at (outside accession number ~~XXXXXX~~) and interpreted as "Positive for malignant cells, Metastatic high grade leiomyosarcoma" which is in agreement with the original diagnosis rendered in this case. The outside pathology report is archived and available from the Pathology Department upon request.

FINAL DIAGNOSIS:

LIVER, US-GUIDED FINE NEEDLE ASPIRATION:

SATISFACTORY FOR INTERPRETATION.

POSITIVE FOR MALIGNANT CELLS.

METASTATIC LEIOMYOSARCOMA (SEE COMMENT).

LXP/LXP

COMMENT:

The FNA contains a spindle cell neoplasm with myxoid change. Immunostains performed on scant cell block material show that the tumor cells are positive for desmin and cladesmon which supports the above diagnosis. The cell block contains insufficient tumor material to evaluate actin and S100 stains.

Source: NCI Genomic Data Commons file 83a0640c-43ed-4246-81e8-49a355814969 (TCGA-K1-A42W.4CD0465A-2CA0-4AB4-AA4A-AD940A53CB49.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).